Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5UN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5UN-06A (Metastatic).

Gross Description: A. "Biopsy mesenteric lymph node." Received is a 0.5 x 0.5 x 0.3 cm aggregate of small tan lymph nodes. Entirely submitted for frozen section in 1 cassette.

B. "Small bowel." Received is a 15.0 cm segment of small bowel with a diameter of 2.5 cm at each end. Occupying the central portion of the specimen is an 8.5 x 7.0 x 7.0 cm lobulated, firm tan mass which protrudes into the lumen of the bowel and nearly constricts the lumen. The mass is 3.5 cm from each stapled end. The serosal surface is smooth; the tumor is protruding. Touch preps made. A portion of tumor is submitted for frozen section in 1 cassette. The tumor is located 2.5 cm from the circumferential margin however there is a sutured vascular structure within 0.5 cm of the protruding mass. The remaining mucosa is edematous with normal mucosal folds.

Microscopic Description: SMALL BOWEL: METASTATIC MELANOMA (8.5 CM GREATEST DIMENSION).

TWO ENTERIC LYMPH NODES NEGATIVE FOR METASTASIS (0/2).

THREE MESENTERIC LYMPH NODES (A) NEGATIVE FOR METASTASIS (0/3).

Diagnosis Details: Small Bowel: Metastatic melanoma

Comments: FROZEN SECTION DIAGNOSIS

ICDO-3
Melanoma, malignant NOS
8720/3
Site: Small intestine NOS
C17.9
Jw 2/19/13

A. LYMPH NODE (MESENTERIC): BENIGN LYMPH NODES.

B. SMALL BOWEL: HIGH-GRADE EPITHELIOID MALIGNANCY, CARCINOMA VS. METASTASIS (MELANOMA IS POSSIBLE). Permanent sections confirm frozen section diagnosis. Immunostains for S100 and MART1 are positive and confirmatory. A cytokeratin immunostain is negative. HMB45 shows patchy positive staining.

Formatted Path Reports: Small Bowel: Metastatic melanoma

SMALL BOWEL: METASTATIC MELANOMA (8.5 CM GREATEST DIMENSION).

TWO ENTERIC LYMPH NODES: NEGATIVE FOR METASTASIS (0/2).

THREE MESENTERIC LYMPH NODES: NEGATIVE FOR METASTASIS (0/3).

FROZEN SECTION DIAGNOSIS

A. LYMPH NODES (MESENTERIC): BENIGN LYMPH NODES.

B. SMALL BOWEL: HIGH-GRADE EPITHELIOID MALIGNANCY, CARCINOMA VS. METASTASIS (MELANOMA IS POSSIBLE). Permanent sections confirm frozen section diagnosis. Immunostains for S100 and MART1 are positive and confirmatory. A cytokeratin immunostain is negative. HMB45 shows patchy positive staining.

Criteria	lw 2/17/13	Yes	No

Source: NCI Genomic Data Commons file c99cd8e4-e864-4317-8290-1f521c378d77 (TCGA-EB-A5UN.BAEBDC12-0ADC-45AC-A604-1825CE629DC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).